Surgical pathology report (de-identified scan), TCGA case TCGA-DU-5849, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-5849-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

Surgical Pathology Report

TCGA--DU-5849

[REDACTED]

Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

=====

CLINICAL HISTORY

[REDACTED] who experienced sudden [REDACTED]
Imaging
studies show a left frontal, heterogeneous, somewhat enhancing intra-axial tumor.

OPERATIVE DIAGNOSES

Left frontal brain lesion.

Operation/Specimen: A: Brain, left frontal, excision biopsy

PATHOLOGICAL DIAGNOSIS:

A. Brain, left frontal lesion, excision: Oligodendroglioma (WHO Grade II) (see comment).

COMMENT

Sections show an oligodendroglioma with areas of microcystic change. Focal

moderately hypercellular areas are present, however mitotic figures are not

conspicuous. Vascular proliferation and necrosis are not seen. p53 shows

scattered weak to moderate reactivity. The Ki-67 labeling index is approximately 4% in the most cellular areas. Positive and negative controls

show appropriate immunoreactivity.

Molecular studies show allelic loss for chromosome segments 1p and 19q, and

the presence of MGMT promotor methylation. EGFRvIII mutation was not detected

(see procedure addenda below).

Electronically Signed Out

[REDACTED]

=====

PROCEDURES/ADDENDA

Loss of Heterozygosity 1p, 19q Assay (LOH)

[REDACTED]

Interpretation

POSITIVE: Allelic loss on chromosome arm 1p and chromosome arm 19q is detected.

[page 2 of 5]
Informative loci are: D1S548, D1S1592, D1S552, D19S219, PLA2G4C
Results-Comments

Testing performed on DNA extracted from tumor paraffin block
and a corresponding blood specimen for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA
(baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3
markers

on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and
D1S496 as
backup markers) and the 3 markers on 19q are D19S219, D19S412, and
PLA2G4C

(with D19S606 and D19S1182 as backup). All markers are microsatellites
(2 or 4

nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat)
polymorphism. The markers were selected based on heterozygosity score,
amplicon size, and ease of interpretation. The backup markers are used
if the

first line markers at that chromosome arm are uninformative or
otherwise

ambiguous in their interpretation. LOH at all informative loci on each
chromosomal arm represents the typical finding in oligodendrogliomas
with 1p

and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results
from a

stand-alone diagnostic test. This test was developed and its
performance

characteristics determined by the [REDACTED] as
[REDACTED]. It has not been cleared or
approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA
has

determined that such clearance or approval is not necessary. These
results are

provided for informational purposes only, and should be interpreted
only in

the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in
the sample

may preclude the detection of allelic loss.

Electronically Signed Out

[REDACTED]

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT
promoter

have been shown to benefit from therapy with alkylating agents.

Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA
followed

by real-time PCR amplification (MethyLight) of methylated and
unmethylated DNA

[page 3 of 5]
sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA.

Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by [REDACTED]. It has not been cleared or approved for

specific uses by the U.S. Food and Drug Administration (FDA). The FDA has

determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

[REDACTED]
PCR for EGFR variant III mutation

[REDACTED]
NEGATIVE - No evidence of EGFRvIII mutation is detected
Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from tumor paraffin block

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it is amplified, overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in glioblastoma. Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct

subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been

shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor

suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is

then amplified using standard PCR technique for DNA templates. PCR products

[page 4 of 5]
are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] as required by [REDACTED]. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.
Electronically Signed Out

=====

INTRA-OPERATIVE CONSULTATION

A.

Brain, left frontal, excision biopsy: Glioma, infiltrating [REDACTED] oligo, mixed?). [REDACTED] Touch preparation smears performed at [REDACTED] and [REDACTED] results reported to the Physician of Record. [REDACTED]

GROSS DESCRIPTION

A.

Brain, left frontal, excision biopsy: Received fresh, large fragment, 2.2 x 2.0 x 1.4 cm. Brain tissue, semi firm, cerebral cortex and white matter with lost demarkation and expansion of the cortex. No necrosis or hemorrhage. Serially sectioned, A1-A4.

ICD-9(S):

225.0 225.0

Histo Data

Part A: Brain, left frontal, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
MGMT-curls x 1	1	[REDACTED]	Also run 1p19q
Rct 1 H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	

[page 5 of 5]
MIB1-DA x 1	2
P53DO7 x 1	2
Rct 1 H/E x 1	2
H/E x 1	3
H/E x 1	4
*** End of Report ***	

Source: NCI Genomic Data Commons file b07178e5-a64d-4120-8394-39d460b05334 (TCGA-DU-5849.7EC64754-8800-44DD-A5CC-2A9E8FC8BB27.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).